Somatic mutation profile of tumor specimen TCGA-FU-A3EO-01A (aliquot TCGA-FU-A3EO-01A-11D-A20U-09) from TCGA case TCGA-FU-A3EO, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 55.3 years (20,207 days).
Specimen TCGA-FU-A3EO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2e99eb2c-b24f-42ed-b566-97ee21c59946.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FU-A3EO-11A (Solid Tissue Normal), aliquot TCGA-FU-A3EO-11A-13D-A20U-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d5e4bbd1-9e6c-4ffb-bad6-51739386fac7

The open-access MAF lists 58 somatic variants for this specimen: 41 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 16, Intron 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 18/38 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS19 | c.1685C>T p.S562F | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV50743654; called by muse, mutect2, varscan2
- ADGRB2 | c.2975G>A p.S992N | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.086); catalogued as COSV57076593; called by muse, mutect2, varscan2
- AGTPBP1 | c.1201A>G p.T401A (on ENST00000357081 / NM_001330701.2; = p.T361A on NM_015239.2) | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV100430356; called by muse, mutect2, varscan2
- ALPK3 | c.3868G>A p.G1290S | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760195718, COSV51936757; called by muse, mutect2, varscan2
- ANXA2 | c.55A>G p.T19A | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV60317946; called by muse, mutect2
- APOH | c.920G>A p.C307Y | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765836638, COSV52772363, COSV52773747; called by muse, mutect2, varscan2
- ASB17 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs771251338, COSV52410594; called by muse, mutect2, varscan2
- ATP10B | c.1847C>T p.T616M | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.039); catalogued as rs754939093, COSV59159475; called by muse, mutect2, varscan2
- C2CD3 | c.767G>T p.G256V | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); catalogued as COSV58096749; called by muse, mutect2, varscan2
- CACNA1I | c.933T>G p.N311K | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs770599967, COSV60802748; called by muse, mutect2, varscan2
- CACNB4 | c.122C>T p.T41I | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.969); catalogued as COSV52398889; called by muse, mutect2, varscan2
- CTNNA2 | c.2278C>T p.R760C | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58166790, COSV58184227; called by muse, mutect2, varscan2
- DACT1 | c.691G>A p.A231T | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60022415; called by muse, mutect2, varscan2
- DNAH11 | c.2827T>C p.F943L | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV60968530; called by muse, mutect2, varscan2
- DPYSL5 | c.1310T>C p.L437P | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.59); catalogued as COSV56514500; called by muse, mutect2, varscan2
- DTNB | c.917C>G p.S306C | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV56476768, COSV99978109; called by muse, mutect2
- HAUS5 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs968436885, COSV52549033; called by muse, mutect2, varscan2
- HRC | c.1492G>A p.D498N | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); catalogued as rs1199947562, COSV53257726; called by muse, mutect2, varscan2
- HSPA2 | c.514C>A p.R172S | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.241); catalogued as COSV55970754; called by muse, mutect2, varscan2
- IKBKE | c.740C>T p.A247V | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV65626414; called by muse, mutect2, varscan2
- IPO9 | c.2260C>T p.R754C | Missense Mutation (SNP) | VAF 67/118 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV64234046; called by muse, mutect2, varscan2
- LRBA | c.1958C>G p.S653C | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV63960269; called by muse, mutect2, varscan2
- LRIF1 | c.1978G>C p.V660L | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV63898040; called by muse, mutect2, varscan2
- MCF2L2 | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs1185481638, COSV61054265; called by muse, mutect2, varscan2
- NELL1 | c.5C>T p.P2L | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.005); catalogued as rs1162842438, COSV54297731, COSV54315240; called by muse, mutect2, varscan2
- NSMAF | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs199548636, COSV50683540; called by muse, mutect2, varscan2
- RIN2 | c.2467C>T p.R823W (on ENST00000255006 / NM_001242581.1; = p.R774W on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772994328, COSV54791454; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RNF128 | c.157G>A p.V53I | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.061); catalogued as rs146627932, COSV60945012; called by muse, mutect2, varscan2
- RPA1 | c.1703G>T p.R568L | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.251); catalogued as COSV54611316, COSV99627929; called by muse, mutect2, varscan2
- RPL3 | c.1183G>A p.D395N | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as COSV53366128; called by muse, mutect2, varscan2
- SEC16B | c.2404C>T p.P802S | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.356); catalogued as COSV57624442; called by muse, mutect2, varscan2
- SPTA1 | c.1402C>T p.R468C | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.55); catalogued as rs565907779, COSV63749834, COSV63750786; called by muse, mutect2, varscan2
- TENM2 | c.6118T>C p.F2040L (on ENST00000518659 / NM_001122679.2; = p.F1801L on NM_001080428.3) | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.995); catalogued as COSV69136676; called by muse, mutect2, varscan2
- THOC2 | c.2347T>G p.F783V | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55545139; called by muse, mutect2, varscan2
- TUBGCP6 | c.1840C>T p.L614F | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs368583248, COSV99955444; called by muse, mutect2, varscan2
- TXNDC11 | c.2516C>T p.A839V (on ENST00000356957 / NM_001303447.2; = p.A812V on NM_015914.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/35 reads (69%) | SIFT tolerated (0.07); PolyPhen benign (0.276); catalogued as COSV51601449; called by muse, mutect2, varscan2
- ZW10 | c.1260T>G p.H420Q | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52318315; called by muse, mutect2, varscan2
- ARV1 | c.253G>T p.A85S | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.341); called by muse, mutect2
- POLR1A | c.692_693del p.V231Afs*10 | Frame Shift Del (DEL) | VAF 9/28 reads (32%) | called by mutect2, pindel, varscan2
- RHOB | c.470_471insTG p.E158Afs*84 | Frame Shift Ins (INS) | VAF 8/21 reads (38%) | called by mutect2, pindel*, varscan2
- BRWD1 | c.4161C>T p.S1387= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as COSV100314259; called by muse, mutect2, varscan2
- CMC4 | c.136A>C p.R46= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as COSV62900129; called by muse, mutect2, varscan2
- EFCAB14 | c.1347C>T p.D449= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as rs376760911; called by muse, mutect2, varscan2
- FLNC | c.7059T>C p.G2353= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV57960604; called by muse, mutect2, varscan2
- GOPC | c.1086G>A p.E362= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV50003105; called by mutect2, varscan2
- MAGEH1 | c.207G>A p.S69= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as COSV61678938; called by muse, mutect2, varscan2
- MS4A3 | c.12C>T p.H4= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as rs759613400, COSV53936692, COSV53937148; called by muse, mutect2, varscan2
- OLIG2 | c.252G>A p.S84= | Silent (SNP) | VAF 25/60 reads (42%) | catalogued as rs1221027032, COSV100324354; called by muse, mutect2
- OR4K1 | c.855C>A p.I285= | Silent (SNP) | VAF 21/115 reads (18%) | catalogued as rs1338822299, COSV53461428; called by muse, mutect2, varscan2
- RASGRF2 | c.2799C>T p.F933= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs371857641, COSV54126344; called by muse, mutect2, varscan2
- SBK2 | c.369C>T p.Y123= | Silent (SNP) | VAF 34/73 reads (47%) | catalogued as rs200066533, COSV60013308; called by muse, mutect2, varscan2
- SDHC | c.366C>T p.F122= | Silent (SNP) | VAF 30/107 reads (28%) | catalogued as rs868596979, COSV61368988; called by muse, mutect2, varscan2
- SPAG6 | c.108G>A p.T36= | Silent (SNP) | VAF 28/62 reads (45%) | catalogued as rs1018566986, COSV57622331; called by muse, mutect2, varscan2
- TBX20 | c.105G>A p.T35= | Silent (SNP) | VAF 29/73 reads (40%) | catalogued as rs771888980, COSV68783564, COSV68784788; called by muse, mutect2, varscan2
- TTN | c.7774C>T p.L2592= (on ENST00000591111; = p.L2546= on NM_003319.4) | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV60214458; called by muse, mutect2, varscan2
- XKRX | c.864C>T p.F288= | Silent (SNP) | VAF 18/77 reads (23%) | catalogued as COSV60708789; called by muse, mutect2, varscan2
- AZIN2 | c.1029+3708G>A | Intron (SNP) | VAF 45/150 reads (30%) | catalogued as rs372074592; called by muse, mutect2, varscan2
